Somatic mutation profile of tumor specimen 0DJO5J from CCDI case PBBWZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 14.8 years (5,419 days).
Specimen 0DJO5J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53f5a3e0-6236-4b2a-9979-abb55cc4c4b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f852ac13-28ec-4013-95f5-88236d7c651a

The open-access MAF lists 59 somatic variants for this specimen: 34 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 16, Intron 7, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 89/428 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.767); catalogued as rs202211381; called by muse, mutect2, varscan2
- A2ML1 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs376705356, COSV55298734; called by muse, mutect2, varscan2
- ADGRA2 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 107/537 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as rs150879838; called by muse, mutect2, varscan2
- CACNA1I | c.5878A>G p.M1960V | Missense Mutation (SNP) | VAF 91/621 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1159217302; called by muse, mutect2, varscan2
- CSF2RB | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200666918; called by muse, mutect2, varscan2
- DHRS4 | c.567G>T p.L189F | Missense Mutation (SNP) | VAF 68/716 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769885588; called by muse, mutect2
- DIS3L | c.1928G>A p.R643Q (on ENST00000319212 / NM_001143688.3; = p.R560Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778702920, COSV100054910; called by muse, mutect2, varscan2
- FRMD4A | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs761548207; called by muse, mutect2, varscan2
- IL16 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748445175, COSV57269172; called by muse, mutect2, varscan2
- IRX1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57360666; called by muse, mutect2, varscan2
- MIB2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 101/638 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as rs770733872; called by muse, mutect2, varscan2
- OR6C70 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs375430845, COSV59244897; called by muse, mutect2, varscan2
- PDGFRL | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 79/499 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.484); catalogued as rs764312458; called by muse, mutect2, varscan2
- POU2F2 | c.887G>A p.R296Q (on ENST00000526816 / NM_001207025.3; = p.R280Q on NM_002698.5) | Missense Mutation (SNP) | VAF 74/768 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100657579; called by muse, mutect2
- PPP2R5D | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 109/635 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.158); catalogued as rs757857436; called by muse, mutect2, varscan2
- RRBP1 | c.2909G>A p.R970Q (on ENST00000377813 / NM_001365613.2; = p.R537Q on NM_004587.3) | Missense Mutation (SNP) | VAF 102/635 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs768096329, COSV55699610; called by muse, mutect2, varscan2
- SMARCD3 | c.955C>T p.R319W (on ENST00000262188 / NM_001003801.2; = p.R306W on NM_003078.4) | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50389879; called by muse, mutect2, varscan2
- SNRPA | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as rs768970890; called by muse, mutect2, varscan2
- SYNJ1 | c.3809C>T p.S1270L | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1052497631, COSV59144480; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS14 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- APOB | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 122/408 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ELOVL4 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 63/409 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GZMM | c.328_338del p.N110Afs*22 | Frame Shift Del (DEL) | VAF 28/264 reads (11%) | called by mutect2, pindel
- LIN28A | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 62/421 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MCM2 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV1 | c.1802C>G p.T601S | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- SEC16A | c.2338_2386delinsGCATTGGTGCTTCTGAGAACCTTGAGAATCCTCCC p.Q780Afs*37 | Frame Shift Del (DEL) | VAF 31/345 reads (9%) | called by pindel, varscan2*
- SIK3 | c.2537C>A p.S846* (on ENST00000445177 / NM_001366686.2; = p.S804* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | called by muse, mutect2, varscan2
- SLC22A2 | c.827T>G p.F276C | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- SLC22A4 | c.716T>C p.F239S | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- SMARCA4 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 106/380 reads (28%) | called by muse, mutect2, varscan2
- SUFU | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 154/579 reads (27%) | called by muse, mutect2, varscan2
- ZBTB9 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BRWD1 | c.57C>T p.Y19= | Silent (SNP) | VAF 54/566 reads (10%) | catalogued as rs775106300; called by muse, mutect2
- DRD4 | c.897C>A p.P299= | Silent (SNP) | VAF 30/199 reads (15%) | called by muse, varscan2
- ERC2 | c.2853C>T p.D951= | Silent (SNP) | VAF 45/207 reads (22%) | catalogued as rs570345623; called by muse, mutect2, varscan2
- IQSEC3 | c.3183G>T p.P1061= | Silent (SNP) | VAF 57/284 reads (20%) | called by muse, mutect2, varscan2
- KNG1 | c.585T>C p.F195= | Silent (SNP) | VAF 45/353 reads (13%) | called by muse, mutect2, varscan2
- LAMA5 | c.6000G>A p.G2000= | Silent (SNP) | VAF 83/508 reads (16%) | catalogued as COSV99439078; called by muse, mutect2, varscan2
- MCM2 | c.1809C>T p.A603= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- MGAM | c.1461C>A p.L487= | Silent (SNP) | VAF 58/474 reads (12%) | called by muse, mutect2, varscan2
- PLCB1 | c.918C>T p.V306= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as COSV62054522; called by muse, mutect2, varscan2
- PRPF8 | c.372A>T p.G124= | Silent (SNP) | VAF 126/474 reads (27%) | called by muse, varscan2
- PSD3 | c.1257G>A p.E419= | Silent (SNP) | VAF 41/301 reads (14%) | called by muse, mutect2, varscan2
- RBM45 | c.60G>T p.L20= | Silent (SNP) | VAF 69/368 reads (19%) | called by muse, mutect2, varscan2
- SASH1 | c.3195C>T p.P1065= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as rs758923254, COSV66560635; called by muse, mutect2, varscan2
- SIRPA | c.1080C>T p.T360= | Silent (SNP) | VAF 67/439 reads (15%) | catalogued as rs200639123; called by muse, mutect2, varscan2
- TTC28 | c.4905C>T p.A1635= | Silent (SNP) | VAF 77/411 reads (19%) | catalogued as rs750155927; called by muse, mutect2, varscan2
- UTRN | c.435G>A p.S145= | Silent (SNP) | VAF 39/355 reads (11%) | catalogued as rs377032020; called by muse, mutect2, varscan2
- BIRC6 | c.13144+8252A>T | Intron (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- GARS1 | c.*46A>C | 3'UTR (SNP) | VAF 30/384 reads (8%) | catalogued as rs755138620; called by muse, mutect2
- IRF5 | c.447+84C>T | Intron (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- MRAP | c.107-28C>T | Intron (SNP) | VAF 23/136 reads (17%) | catalogued as rs755852895; called by muse, mutect2, varscan2
- MYBPH | c.*6C>T | 3'UTR (SNP) | VAF 52/254 reads (20%) | catalogued as rs771118475; called by mutect2, varscan2
- NRXN1 | c.3719-1436G>T | Intron (SNP) | VAF 24/220 reads (11%) | catalogued as COSV60486133; called by muse, mutect2, varscan2
- ODF2L | c.436-18A>C | Intron (SNP) | VAF 37/257 reads (14%) | called by muse, mutect2, varscan2
- THOC5 | c.714+33C>A | Intron (SNP) | VAF 37/223 reads (17%) | called by muse, mutect2, varscan2
- TPP2 | c.785-86A>G | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
